Somatic mutation profile of tumor specimen TARGET-30-PAPHPE-01A (aliquot TARGET-30-PAPHPE-01A-01W) from TARGET case TARGET-30-PAPHPE, project TARGET-NBL (Neuroblastoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Neuroblastoma, NOS; Tissue or organ of origin: Abdomen, NOS; Age at diagnosis: 2.2 years (806 days).
Specimen TARGET-30-PAPHPE-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a04a8b0f-f8c9-40da-a9d6-61d3ae1a6763.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-30-PAPHPE-10A (Blood Derived Normal), aliquot TARGET-30-PAPHPE-10A-01W; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e9081426-cabe-471e-a756-46dde771cbef

The open-access MAF lists 11 somatic variants for this specimen: 9 protein-altering or splice-affecting, 2 silent.
By variant classification: Missense Mutation 7, Silent 2, Nonsense Mutation 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CHMP2A | c.392G>A p.R131Q | Missense Mutation (SNP) | VAF 76/200 reads (38%) | SIFT tolerated (0.06); PolyPhen benign (0.028); catalogued as rs753785301, COSV53397763; called by muse, mutect2, varscan2
- DNAH2 | c.2190C>A p.C730* | Nonsense Mutation (SNP) | VAF 34/111 reads (31%) | catalogued as COSV66723218; called by muse, mutect2, varscan2
- HORMAD2 | c.558C>G p.Y186* | Nonsense Mutation (SNP) | VAF 41/168 reads (24%) | catalogued as COSV60899833; called by muse, mutect2, varscan2
- PGLYRP4 | c.982G>T p.D328Y | Missense Mutation (SNP) | VAF 73/834 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.918); catalogued as COSV62834770; called by muse, mutect2
- SPOCK3 | c.313G>A p.D105N | Missense Mutation (SNP) | VAF 75/289 reads (26%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.576); catalogued as COSV62731754; called by muse, mutect2, varscan2
- TULP4 | c.355G>C p.E119Q | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as COSV65578746; called by muse, mutect2, varscan2
- ZNF142 | c.1166C>T p.P389L (on ENST00000411696 / NM_001379660.1; = p.P189L on NM_001105537.4 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 4/64 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as rs1048079372; called by muse, mutect2
- FAM47B | c.1834G>T p.A612S | Missense Mutation (SNP) | VAF 34/454 reads (7%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.64); called by muse, mutect2
- NSUN2 | c.696C>A p.S232R | Missense Mutation (SNP) | VAF 12/148 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.043); called by muse, mutect2
- MED12L | c.3786A>G p.K1262= | Silent (SNP) | VAF 9/144 reads (6%) | called by muse, mutect2
- ZNF746 | c.303C>A p.G101= | Silent (SNP) | VAF 58/222 reads (26%) | catalogued as COSV61408364; called by muse, mutect2, varscan2
